Somatic mutation profile of tumor specimen TCGA-AO-A0JM-01A (aliquot TCGA-AO-A0JM-01A-21W-A071-09) from TCGA case TCGA-AO-A0JM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 40.1 years (14,653 days).
Specimen TCGA-AO-A0JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04b1574d-b35c-46c4-aa8f-bd152b3b59bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JM-10A (Blood Derived Normal), aliquot TCGA-AO-A0JM-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a6315a2-3842-481d-aced-316787610fee

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 4, 5'Flank 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8977C>T p.R2993* | Nonsense Mutation (SNP) | VAF 138/218 reads (63%) | catalogued as rs770641163, CM960113, COSV53732836; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTA2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1057521105, CM092903, COSV56518226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.2627A>T p.Y876F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs372966603; called by muse, mutect2
- ADAMTS5 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV53175743, COSV53185907; called by muse, mutect2, varscan2
- BMT2 | c.879G>A p.W293* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV51781411; called by muse, mutect2, varscan2
- BRPF3 | c.2023T>G p.F675V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60210098; called by muse, mutect2, varscan2
- CEP128 | c.1443C>A p.D481E | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252145126, COSV55391926; called by muse, mutect2
- CHL1 | c.1408C>T p.R470W (on ENST00000397491 / NM_001253387.1; = p.R486W on NM_006614.4) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141644867; called by muse, mutect2, varscan2
- DOCK7 | c.4148G>T p.S1383I (on ENST00000635253 / NM_001367561.1; = p.S1352I on NM_033407.3) | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV52022537; called by muse, mutect2, varscan2
- FBXO27 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as COSV53073193; called by muse, mutect2, varscan2
- FSD1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1414231164, COSV55699183; called by mutect2, varscan2
- GABRR3 | c.687G>C p.M229I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72084409; called by muse, mutect2, varscan2
- GBE1 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV70103304; called by muse, mutect2, varscan2
- GOSR1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as rs1199940538, COSV56719849; called by muse, mutect2, varscan2
- GTF3C3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV55834801; called by muse, mutect2, varscan2
- GTSE1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1263085575, COSV71889914; called by muse, mutect2, varscan2
- HIVEP1 | c.4604C>T p.T1535M | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as rs371327892; called by muse, mutect2
- LSMEM1 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV57197214; called by muse, mutect2, varscan2
- MED1 | c.3527G>T p.G1176V | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.609); catalogued as COSV56128803; called by muse, mutect2
- MTF2 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64772429; called by muse, mutect2, varscan2
- PLD3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs145892029; called by muse, mutect2, varscan2
- PPP1R9A | c.2859A>C p.L953F | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV56912888; called by muse, mutect2, varscan2
- PRKDC | c.7076A>C p.K2359T | Missense Mutation (SNP) | VAF 94/166 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58065295; called by muse, mutect2, varscan2
- SLFN13 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV53195910; called by muse, mutect2
- SLFN13 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV53195918; called by muse, mutect2
- SPOP | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 31/443 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs890324763, COSV61656037; called by muse, mutect2
- SRCAP | c.495G>A p.V165= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52681842; called by muse, mutect2, varscan2
- SRSF5 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1381655941, COSV67936571; called by muse, mutect2, varscan2
- SYNE2 | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58362850; called by muse, mutect2, varscan2
- TCHHL1 | c.2380G>T p.G794C | Missense Mutation (SNP) | VAF 87/487 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV64287815; called by muse, mutect2, varscan2
- TFAP2A | c.1049T>G p.F350C (on ENST00000482890; = p.F342C on NM_001032280.3) | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60237954; called by muse, mutect2, varscan2
- TTLL4 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs377347204; called by muse, mutect2, varscan2
- CHST9 | c.724dup p.Y242Lfs*19 | Frame Shift Ins (INS) | VAF 68/363 reads (19%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.1925_1926del p.G642Afs*24 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.3078C>T p.A1026= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV63023360; called by muse, mutect2, varscan2
- AFF3 | c.1488C>T p.Y496= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs1017935299; called by muse, mutect2
- ANKRD11 | c.2967C>T p.S989= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs375678160; called by muse, mutect2, varscan2
- BRPF3 | c.2022T>A p.I674= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV60210086; called by muse, mutect2, varscan2
- C3orf20 | c.609C>T p.S203= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs767591433, COSV53789673; called by muse, mutect2, varscan2
- DAW1 | c.660C>T p.A220= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as rs1042819578, COSV59369522; called by muse, mutect2, varscan2
- MDM4 | c.780T>G p.T260= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV65796890; called by muse, mutect2, varscan2
- RASSF2 | c.144C>T p.D48= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs751229585, COSV65082989, COSV65083386; called by muse, mutect2, varscan2
- SNX6 | c.906C>G p.L302= (on ENST00000652385; = p.L174= on NM_021249.5) | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV61920755; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505373 G>C | 5'Flank (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505705 G>A | 5'Flank (SNP) | VAF 57/339 reads (17%) | catalogued as rs1012868973; called by muse, mutect2, varscan2
